Gene-level copy-number profile of tumor specimen TCGA-2G-AAHC-01A from TCGA case TCGA-2G-AAHC, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.1 years (12,105 days).
Specimen TCGA-2G-AAHC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.5f863909-0821-448c-a025-4c1adf1f38c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAHC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de7c99dd-6e05-46c3-bbb6-e081be883fce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,335; copy number 2: 22,194; copy number 3: 28,101; copy number 4: 6,970; copy number 5: 460; copy number 6: 430; copy number 7: 121; copy number 8: 46; copy number 10: 161.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAHC-01A-11D-A42X-01): tumor purity 0.3, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 328 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,636,547–75,161,533, 29 genes, copy number 7: AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P, LRRIQ3, FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2.
- chr1:116,514,534–119,140,654, 46 genes, copy number 8 (within-gene range 3–8): CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1, LINC02868, GAPDHP64, NEFHP1, CD2, FTH1P22, AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12.
- chr3:156,671,862–162,601,792, 92 genes, copy number 7 (broad region; genes not listed).
- chr3:183,635,610–191,330,536, 161 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
